ORGANOID case 44 — Pancreas Cancer Organoid Profiling (ORGANOID-PANCREATIC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/1c49e2cd-e5f3-4fbd-a8f0-4714ed8fb818

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Adenocarcinoma, NOS: Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Pancreas, NOS; AJCC pathologic stage: Stage IIA.

Biospecimens (1 sample)
- Sample S78: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Specimen type: 3D Organoid.
